OHSU case 2240 — OHSU-CNL: Philadelphia-Negative Neutrophilic Leukemias (CNL/aCML/MDS/MPNu)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Chronic Myeloproliferative Disorders; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/60a9e44c-0444-4bd3-969b-032105aec1a4

Demographics
Vital status: Dead.

Diagnoses (1)
1. Myloproliferative neoplasm, unclassifiable: ICD-O-3 morphology code: 9975/3; Tissue or organ of origin: Bone marrow; Days to last follow up: 1,099 days (3.0 years).

Biospecimens (1 sample)
- Sample 1299D: Tissue type: Tumor; Preservation method: Snap Frozen.
